Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3461, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3461-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):

Left Kidney resection with Adrenal gland

Gross Description:

Received in one part.

Source of Tissue: 1. Labeled #1, "left kidney and adrenal"

Gross Description: Received fresh labeled, left kidney and adrenal". It consists of a kidney with surrounding perinephric fat weighing a total of 844 grams and measuring 22 x 16 x 8.5 cm. The attached ureter measures 9.5 cm in length and 0.3 cm in diameter. The ureter is opened to show a smooth tan-pink mucosa with no papillary structures noted. The specimen is bisected to show a 10.5 x 6.5 x 4 cm kidney. A well-demarcated, golden-yellow firm 3.5 x 3 x 3 cm nodule is identified at the superior pole and comes within less than 0.1 cm of the renal capsule. Grossly the tumor appears confined to the kidney and does not appear to infiltrate the surrounding perinephric fat. The remaining renal parenchyma is tan-pink, soft with no other discrete masses present. The attached adrenal measures 4.5 x 2.5 x 2 cm. The adrenal is sectioned to show a soft golden-yellow cut surface. No obvious discrete masses are present. Representative sections are submitted in 1A-1F.

Designation of Sections: 1A- ureteral and vascular margins, 1B-1C- tumor with closest radial margin inked blue, 1D-1E- tumor with adjacent normal kidney, 1F- adrenal gland

Final Diagnosis:

Left kidney and adrenal:

Renal cell carcinoma, conventional (clear cell) type, [REDACTED] nuclear grade II/IV.

- The 3.5 cm carcinoma is confined to the kidney.

- Angiolymphatic invasion is not identified.

- Surgical resection margins are free of carcinoma.

Adrenal gland with no diagnostic abnormalities recognized.

pTNM: T1a Nx Mx

FCGTL: Chromo15, Chrom45, Interp

[page 2 of 2]
Procedures/Addenda

FC Cytogenetics Solid

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Left Renal Mass

KARYOTYPE: Normal [REDACTED] karyotype: 46,XY[18]

Two additional cells had nonclonal changes. One metaphase contained an extra copy of chromosome 14. Another metaphase was a broken tetraploid cell.

RESULTS: The renal mass was harvested after twelve and fourteen days in culture. The chromosomes from twenty metaphases were counted and analyzed, and four of these metaphases were karyotyped by G-banding. Eighteen cells had a modal chromosome number of 46 and appeared to have a normal karyotype. Two cells had nonclonal changes. One of these metaphases contained an extra copy of chromosome 14. Another metaphase was a broken tetraploid cell. The significance of a single abnormal cell is unclear. It may represent an emerging or undetected clonal cell population, technical artifact, or random event. The normal results may reflect an overgrowth of normal interstitial tissue rather than tumor.

Source: NCI Genomic Data Commons file ae0465e8-e333-45f3-9bba-79b7774f006d (TCGA-AK-3461.EB8E79CD-445C-498D-AD22-CA225C0254AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).